Surgical pathology report (de-identified scan), TCGA case TCGA-41-3915, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-3915-01A (Primary Tumor).

SPECIMEN

- A. Right temporal brain tumor
- B. Right temporal brain tumor

CLINICAL NOTES

PRE-OP DIAGNOSIS: Brain tumor.

FROZEN SECTION DIAGNOSIS

FSA) Right temporal lobe - Glioblastoma multiforme.

GROSS DESCRIPTION

- A. Submitted fresh labeled right temporal brain tumor is
a
1 x 0.5 x 0.5 cm. portion of mucoid orange red tissue
submitted entirely for frozen section.
- B. Received in formalin labeled "right temporal brain
tumor" is an aggregate of pink-tan irregular soft tissue
fragments admixed with clotted blood. The specimens have an
average
measurement of 2 x 1.5 x 0.4 cm. Specimens are entirely submitted
in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

Microscopic sections of the right temporal brain tumor
reveals a malignant astrocytic neoplasm characterized by
proliferation of multinucleated malignant astrocytic cells with
hyperchromasia, nucleomegaly and frequent mitotic activity. The
tumor exhibits neovascularity and large geographic areas of
necrosis. Based on the histologic features, it is characterized as
a Glioblastoma multiforme (Astrocytoma WHO grade IV).

4x2, 14

DIAGNOSIS

- A and B. Brain, right temporal lobe, resection:
Glioblastoma multiforme (Astrocytoma WHO Grade IV).

--- End Of Report ---

Source: NCI Genomic Data Commons file e932e49e-4eb9-4bf6-b95e-a0baf7fd1c1f (TCGA-41-3915.170F0232-2209-4609-8C71-E39CAEC2FFC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).